Somatic mutation profile of tumor specimen ALCH-AELG-TTP1-A (aliquot ALCH-AELG-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AELG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.8 years (25,847 days).
Specimen ALCH-AELG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba13adc0-20e7-4017-8c09-7a36bd849d39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELG-NB1-A (Blood Derived Normal), aliquot ALCH-AELG-NB1-A-2-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c773cbbc-ce3a-463d-b1e2-6c263eb80248

The open-access MAF lists 207 somatic variants for this specimen: 140 protein-altering or splice-affecting, 41 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 41, Intron 9, Nonsense Mutation 6, Splice Site 5, RNA 5, Splice Region 5, Frame Shift Del 5, 3'UTR 4, 3'Flank 4, 5'Flank 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.5351dup p.N1784Kfs*3 | Frame Shift Ins (INS) | VAF 36/192 reads (19%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 63/364 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RYR1 | c.11590+1G>T p.X3864_splice | Splice Site (SNP) | VAF 24/205 reads (12%) | catalogued as rs113928116; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 45/236 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.1466G>T p.R489L | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57775597; called by muse, mutect2
- ADGRB1 | c.2937G>C p.E979D | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV60095034; called by muse, mutect2, varscan2
- ARID1B | c.5626C>T p.P1876S | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV51666255; called by muse, mutect2, varscan2
- ASMT | c.620C>T p.T207I (on ENST00000381229; = p.T235I on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/450 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.393); catalogued as rs753471134; called by muse, mutect2, varscan2
- ASTL | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.411); catalogued as rs748612996, COSV60905632; called by muse, mutect2, varscan2
- ASTN2 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs780254839, COSV57811460; called by muse, mutect2, varscan2
- ATP11C | c.719+1G>T p.X240_splice | Splice Site (SNP) | VAF 72/441 reads (16%) | catalogued as rs1203099951, COSV100557216; called by muse, varscan2
- C5orf34 | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs990488447; called by muse, mutect2, varscan2
- CD96 | c.1628G>A p.W543* (on ENST00000283285 / NM_198196.3; = p.W527* on NM_005816.5) | Nonsense Mutation (SNP) | VAF 64/541 reads (12%) | catalogued as rs747580466; called by muse, mutect2, varscan2
- CDHR4 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1195003292, COSV58525974; called by muse, mutect2, varscan2
- CFAP251 | c.3226G>A p.V1076I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs781099989, COSV56607922; called by muse, mutect2
- CHGB | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1446403942; called by muse, mutect2, varscan2
- CHODL | c.194del p.G65Efs*15 | Frame Shift Del (DEL) | VAF 33/310 reads (11%) | catalogued as COSV54731657; called by mutect2, pindel, varscan2
- CLUAP1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 46/306 reads (15%) | catalogued as COSV100489646; called by muse, mutect2, varscan2
- COL13A1 | c.654C>A p.H218Q (on ENST00000398978 / NM_001130103.2; = p.H180Q on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1055965411, COSV62572469; called by muse, mutect2, varscan2
- CSMD3 | c.5358T>A p.H1786Q (on ENST00000297405 / NM_001363185.1; = p.H1682Q on NM_052900.3) | Missense Mutation (SNP) | VAF 60/518 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs201040975; called by muse, mutect2, varscan2
- DNAH3 | c.9860T>C p.I3287T | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408159650; called by muse, mutect2, varscan2
- ELFN2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68745645; called by muse, mutect2, varscan2
- EMILIN2 | c.2447C>G p.T816S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1055485036; called by muse, mutect2
- EPHB6 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1439028815; called by muse, mutect2
- FAM135B | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52718917; called by muse, mutect2, varscan2
- GBF1 | c.4852A>T p.M1618L (on ENST00000369983 / NM_001377137.1; = p.M1617L on NM_004193.3) | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV100890566; called by muse, mutect2
- HRH3 | c.1316C>A p.S439Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs374913275; called by muse, varscan2
- IGHV3-13 | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.624); catalogued as rs1555437072; called by muse, mutect2, varscan2
- IMPDH1 | c.987C>G p.I329M (on ENST00000470772 / NM_001142573.2; = p.I415M on NM_000883.4) | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100118815; called by muse, mutect2
- ISM1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs377416231; called by muse, mutect2, varscan2
- JADE3 | c.2339G>A p.S780N | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as rs1347385266; called by muse, mutect2
- KANK1 | c.984C>A p.N328K | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs538681873, COSV63216812; called by muse, mutect2, varscan2
- KIF15 | c.4166G>T p.*1389Lext*7 | Nonstop Mutation (SNP) | VAF 20/235 reads (9%) | catalogued as COSV58163693; called by muse, mutect2
- KLHL14 | c.1222C>G p.P408A | Missense Mutation (SNP) | VAF 49/441 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV100839325; called by muse, mutect2, varscan2
- LAMP2 | c.973del p.L325Wfs*21 | Frame Shift Del (DEL) | VAF 50/374 reads (13%) | catalogued as CD154299; called by pindel, varscan2
- LDLRAD1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.224); catalogued as rs1051685218; called by muse, mutect2, varscan2
- LRRC69 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.887); catalogued as COSV59257653; called by muse, mutect2
- MARK4 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99488744; called by muse, mutect2
- MMP26 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs368459718, COSV56173504; called by muse, mutect2, varscan2
- P3H2 | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 52/494 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60029229; called by muse, mutect2, varscan2
- PCDHGA4 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.904); catalogued as rs771155381, COSV53893250; called by muse, mutect2, varscan2
- PDLIM4 | c.671-3C>T | Splice Region (SNP) | VAF 43/238 reads (18%) | catalogued as rs866990886; called by muse, mutect2, varscan2
- PKHD1L1 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 48/436 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs191706684; called by muse, mutect2, varscan2
- PLCB1 | c.595-1G>T p.X199_splice | Splice Site (SNP) | VAF 22/222 reads (10%) | catalogued as COSV62050240; called by muse, mutect2, varscan2
- PLEKHG2 | c.1448-3C>A | Splice Region (SNP) | VAF 18/114 reads (16%) | catalogued as rs1257423286; called by muse, mutect2, varscan2
- ROBO3 | c.3890A>G p.E1297G | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as rs1209549828; called by muse, mutect2, varscan2
- RPL10L | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 52/280 reads (19%) | catalogued as rs746466614, COSV53561197; called by muse, mutect2, varscan2
- RYR1 | c.11590G>C p.V3864L | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.079); catalogued as COSV62104952; called by muse, mutect2, varscan2
- SF3B3 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1293577972, COSV56787161; called by muse, mutect2, varscan2
- SGCD | c.730A>G p.R244G (on ENST00000435422 / NM_001128209.2; = p.R245G on NM_000337.5) | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as rs934639739; called by muse, mutect2, varscan2
- SIPA1L2 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368842985; called by muse, mutect2, varscan2
- SLITRK3 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.784); catalogued as rs779848511; called by muse, mutect2, varscan2
- SPATC1L | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs781525287; called by muse, mutect2, varscan2
- TET3 | c.1843C>G p.R615G | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV99996549; called by muse, mutect2, varscan2
- TMEM185A | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV57559873; called by muse, mutect2
- TMEM26 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 66/487 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs771412504; called by muse, mutect2, varscan2
- TRPA1 | c.3148C>A p.R1050= | Splice Region (SNP) | VAF 32/301 reads (11%) | catalogued as COSV51560710; called by muse, mutect2, varscan2
- ZNF804A | c.3470C>A p.P1157H | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56435888, COSV56452072; called by muse, mutect2, varscan2
- ABCB4 | c.3587T>A p.L1196H (on ENST00000265723 / NM_018849.3; = p.L1189H on NM_000443.4) | Missense Mutation (SNP) | VAF 54/537 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADCY1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- ADGRL2 | c.2511+1_2511+13del p.X837_splice (on ENST00000370717 / NM_001366005.1; = p.X824_splice on NM_012302.4) | Splice Site (DEL) | VAF 26/226 reads (12%) | called by mutect2, pindel
- AKAP9 | c.2080C>G p.Q694E | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ALKBH1 | c.208T>A p.S70T | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANGPTL5 | c.899T>A p.F300Y | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ANK2 | c.4429G>A p.D1477N | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ANKRD27 | c.1071_1073del p.A358del | In Frame Del (DEL) | VAF 34/306 reads (11%) | called by mutect2, pindel
- APBB1IP | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2
- ATXN7L3B | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 144/543 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CAMKV | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP295 | c.3962G>C p.S1321T | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CFAP57 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- CHORDC1 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2
- COL11A2 | c.3899G>A p.G1300E (on ENST00000341947 / NM_080680.3; = p.G1193E on NM_080679.2) | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTAG2 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- CUX2 | c.2585G>C p.G862A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, varscan2
- DHX38 | c.2177C>G p.A726G | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, varscan2
- DIDO1 | c.5929A>T p.R1977* | Nonsense Mutation (SNP) | VAF 24/229 reads (10%) | called by muse, mutect2, varscan2
- DMD | c.8221C>A p.L2741I | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.085); called by muse, mutect2
- DMD | c.8220C>A p.D2740E | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); called by muse, mutect2
- DOP1A | c.6252_6266del p.P2085_A2089del | In Frame Del (DEL) | VAF 22/174 reads (13%) | called by pindel, varscan2
- DTNA | c.1238T>A p.V413D | Missense Mutation (SNP) | VAF 51/510 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- EBP | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ERICH4 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, varscan2
- GABRR3 | c.917C>A p.T306K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2
- GALM | c.886G>C p.A296P | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- GATD1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGCX | c.141T>A p.S47R | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GGH | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- GOLGA6L2 | c.421del p.L141Wfs*62 | Frame Shift Del (DEL) | VAF 32/284 reads (11%) | called by mutect2, pindel, varscan2
- GRIPAP1 | c.1628A>C p.Q543P | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- GYPA | c.232+3A>G | Splice Region (SNP) | VAF 49/426 reads (12%) | called by muse, mutect2, varscan2
- HAO1 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- HHIPL2 | c.856A>T p.N286Y | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXA13 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HPX | c.1221G>C p.L407F | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); called by muse, mutect2
- IFNB1 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 46/416 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.506); called by mutect2, varscan2
- INTS1 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- IRF8 | c.1034G>T p.R345M | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- KCND1 | c.1768G>T p.D590Y | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.3); called by muse, mutect2
- KIAA1109 | c.10426A>T p.T3476S | Missense Mutation (SNP) | VAF 73/510 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KIF26A | c.3193G>T p.A1065S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LAMP2 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); called by muse, varscan2
- MCM9 | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- MGA | c.7444A>G p.I2482V (on ENST00000219905 / NM_001164273.1; = p.I2273V on NM_001080541.2) | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MMP12 | c.459C>G p.N153K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, mutect2
- MTR | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 91/769 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.8632A>T p.T2878S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NIBAN3 | c.1539+1G>T p.X513_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | called by muse, varscan2
- NKX2-1 | c.962dup p.G322Rfs*87 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | called by mutect2, pindel
- NLGN4X | c.1242C>A p.D414E | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NLRP12 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- NR5A1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTNG1 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- PDXDC1 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 32/636 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.131); called by muse, mutect2
- PDZD8 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGB | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PKMYT1 | c.920_965del p.H307Lfs*17 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel
- RHBDF1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- RYR2 | c.6246G>T p.R2082S | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SALL1 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SLC7A13 | c.1346T>A p.F449Y | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SLCO2A1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- SUV39H1 | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SYTL4 | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TDRD12 | c.1345C>G p.P449A | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- TENM1 | c.7717C>G p.H2573D | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TEX11 | c.676T>G p.Y226D (on ENST00000344304; = p.Y211D on NM_031276.3) | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFAP2B | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 53/476 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS11BNL | n.408A>C | Splice Region (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.3819G>T p.E1273D | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TOMM40 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 22/234 reads (9%) | called by mutect2, pindel
- TPR | c.5037T>G p.S1679R | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRIM77 | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- ZFHX4 | c.7717A>G p.T2573A | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- ZNF248 | c.1130A>G p.E377G | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ZNF492 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2
- ZNF548 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF578 | c.1538G>T p.C513F | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2
- ZNF658 | c.1211G>C p.R404T | Missense Mutation (SNP) | VAF 90/723 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ACAN | c.5409A>T p.P1803= | Silent (SNP) | VAF 46/343 reads (13%) | called by muse, mutect2, varscan2
- ADGRF3 | c.999G>A p.A333= (on ENST00000311519 / NM_001145168.1; = p.A134= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as rs146570895; called by muse, mutect2, varscan2
- APOO | c.318A>T p.A106= | Silent (SNP) | VAF 53/320 reads (17%) | called by muse, mutect2, varscan2
- ASTN2 | c.3537A>T p.S1179= (on ENST00000313400 / NM_001365069.1; = p.S1128= on NM_014010.5) | Silent (SNP) | VAF 60/446 reads (13%) | called by muse, mutect2, varscan2
- ATP1A2 | c.1275C>A p.L425= | Silent (SNP) | VAF 27/219 reads (12%) | called by muse, mutect2, varscan2
- ATXN2 | c.627C>T p.A209= (on ENST00000550104; = p.A49= on NM_002973.4) | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, varscan2
- CENPE | c.297A>G p.S99= | Silent (SNP) | VAF 41/346 reads (12%) | called by muse, mutect2, varscan2
- DLG3 | c.597G>T p.A199= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV52088614; called by muse, mutect2, varscan2
- DMRT3 | c.663C>T p.P221= | Silent (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- DSCAM | c.5805G>A p.R1935= | Silent (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- EIF4E2 | c.417G>T p.L139= | Silent (SNP) | VAF 25/199 reads (13%) | called by muse, mutect2, varscan2
- FAT2 | c.7710G>T p.T2570= | Silent (SNP) | VAF 62/314 reads (20%) | catalogued as COSV55827280; called by muse, mutect2, varscan2
- GABRB2 | c.1062C>A p.R354= | Silent (SNP) | VAF 50/179 reads (28%) | called by muse, mutect2, varscan2
- IVL | c.1113G>T p.L371= | Silent (SNP) | VAF 20/136 reads (15%) | called by muse, varscan2
- KLHL6 | c.1014C>A p.T338= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- LRCH2 | c.244C>A p.R82= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- MAGEB16 | c.615C>A p.L205= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as COSV67874211; called by muse, mutect2, varscan2
- MAPK12 | c.915G>A p.A305= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs765790100, COSV53132514; called by muse, mutect2, varscan2
- MYOF | c.2778T>G p.G926= | Silent (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- NDUFB8 | c.294G>A p.R98= | Silent (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- OR2L8 | c.924C>T p.C308= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100594142; called by muse, varscan2
- PDK3 | c.834A>G p.K278= | Silent (SNP) | VAF 29/268 reads (11%) | called by muse, mutect2, varscan2
- PLEK | c.1041A>T p.R347= | Silent (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2
- PRPS2 | c.57G>T p.V19= | Silent (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- RHCG | c.1062G>C p.V354= | Silent (SNP) | VAF 17/193 reads (9%) | called by muse, mutect2
- RPA4 | c.124C>A p.R42= | Silent (SNP) | VAF 24/307 reads (8%) | called by muse, mutect2
- RYR1 | c.6960C>T p.D2320= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as rs1271691326; called by muse, mutect2
- SBNO1 | c.1506A>G p.E502= (on ENST00000420886; = p.E501= on NM_018183.5) | Silent (SNP) | VAF 40/329 reads (12%) | catalogued as rs1451724798; called by muse, mutect2, varscan2
- SERPINF1 | c.957G>T p.L319= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV54616220; called by muse, mutect2, varscan2
- SHARPIN | c.444G>A p.P148= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs775537225; called by muse, mutect2, varscan2
- SLC27A5 | c.1653C>T p.L551= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV54019482; called by muse, mutect2
- SLC3A2 | c.210G>A p.T70= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as rs768058399; called by muse, mutect2, varscan2
- SLC44A2 | c.754C>T p.L252= | Silent (SNP) | VAF 38/284 reads (13%) | called by muse, mutect2, varscan2
- SNTG2 | c.945C>T p.T315= | Silent (SNP) | VAF 39/369 reads (11%) | catalogued as rs768058163, COSV57966445; called by muse, mutect2, varscan2
- SPON2 | c.330C>A p.I110= | Silent (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- TAF1L | c.4350T>C p.R1450= | Silent (SNP) | VAF 60/383 reads (16%) | catalogued as COSV54256832; called by muse, mutect2, varscan2
- TEX15 | c.8043A>T p.I2681= (on ENST00000256246; = p.I3064= on NM_001350162.2) | Silent (SNP) | VAF 52/358 reads (15%) | called by muse, mutect2, varscan2
- TRIM71 | c.1776G>A p.P592= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as rs745594474, COSV101070472; called by muse, mutect2, varscan2
- TTN | c.9264A>T p.V3088= (on ENST00000591111; = p.V3042= on NM_003319.4) | Silent (SNP) | VAF 84/623 reads (13%) | called by muse, mutect2, varscan2
- ZNF540 | c.1200G>T p.R400= | Silent (SNP) | VAF 49/489 reads (10%) | catalogued as COSV57109602; called by muse, mutect2, varscan2
- ZNF599 | c.1254C>A p.T418= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as rs547493229, COSV61395740; called by muse, mutect2, varscan2
- AC132807.2 | n.271C>T | RNA (SNP) | VAF 44/384 reads (11%) | catalogued as rs1433996164; called by muse, mutect2, varscan2
- AP003393.1 | n.514+851C>A | Intron (SNP) | VAF 21/211 reads (10%) | called by muse, mutect2
- ARRDC1 | c.-28C>T | 5'UTR (SNP) | VAF 8/38 reads (21%) | catalogued as rs773926944; called by muse, varscan2
- CIAPIN1 | c.556+46G>C | Intron (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- CIAPIN1 | c.556+45G>T | Intron (SNP) | VAF 25/190 reads (13%) | called by muse, mutect2, varscan2
- DCHS2 | n.7232del | RNA (DEL) | VAF 41/363 reads (11%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.10626+44A>T | Intron (SNP) | VAF 58/337 reads (17%) | called by muse, mutect2, varscan2
- GBX2 | c.523+278G>C | Intron (SNP) | VAF 16/138 reads (12%) | catalogued as COSV100103552; called by muse, mutect2, varscan2
- GLTPP1 | chr11:18188962 G>T | 5'Flank (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- KDM1B | chr6:18222264 T>C | 3'Flank (SNP) | VAF 8/72 reads (11%) | catalogued as rs1253743583; called by muse, mutect2
- LARP6 | c.200+2244C>T | Intron (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- LINC01387 | n.271C>A | RNA (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- LRSAM1 | c.*38C>A | 3'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
- NDUFS2 | c.702+41C>G | Intron (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2
- NOC2LP2 | n.453C>G | RNA (SNP) | VAF 36/363 reads (10%) | called by muse, mutect2, varscan2
- OR9G4 | chr11:56741014 C>G | 3'Flank (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- PNCK | chrX:153674114 C>G | 5'Flank (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2, varscan2
- RBM41 | chrX:107065726 A>C | 3'Flank (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- RBM41 | chrX:107065728 G>T | 3'Flank (SNP) | VAF 25/246 reads (10%) | catalogued as COSV99179761; called by muse, mutect2
- RN7SL484P | chr15:99790401 G>T | 5'Flank (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- SLC6A20 | c.*565C>T | 3'UTR (SNP) | VAF 12/85 reads (14%) | catalogued as rs926438302; called by mutect2, varscan2
- TOX2 | c.*25G>T | 3'UTR (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- TTC41P | n.2859C>A | RNA (SNP) | VAF 70/230 reads (30%) | catalogued as rs1369443851; called by muse, mutect2, varscan2
- USP12 | c.*18G>C | 3'UTR (SNP) | VAF 38/261 reads (15%) | called by muse, mutect2, varscan2
- WDR45 | c.235+62C>A | Intron (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- YIF1B | c.789+495C>T | Intron (SNP) | VAF 17/97 reads (18%) | catalogued as rs1271958242; called by muse, mutect2, varscan2
